Somatic mutation profile of tumor specimen TCGA-A2-A0ST-01A (aliquot TCGA-A2-A0ST-01A-12D-A099-09) from TCGA case TCGA-A2-A0ST, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.8 years (22,922 days).
Specimen TCGA-A2-A0ST-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba71c121-3546-45db-95d1-d03c767a41b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0ST-10A (Blood Derived Normal), aliquot TCGA-A2-A0ST-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30b14023-2933-40a0-9eb1-17ef89302b6c

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 7, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP21 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64541068; called by muse, mutect2, varscan2
- BLOC1S5 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs1372577166, COSV99789546; called by muse, mutect2
- CCDC142 | c.596C>A p.S199* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99282326; called by muse, mutect2
- FANCE | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as COSV57689012; called by muse, mutect2, varscan2
- GPR153 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1035922375, COSV100928597; called by muse, mutect2
- NDUFS1 | c.1868T>G p.I623R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201634181; called by muse, mutect2
- PEX11B | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100994670, COSV65195898; called by muse, mutect2, varscan2
- SND1 | c.2662G>T p.A888S | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as rs1295852424, COSV100690982; called by muse, mutect2
- TTN | c.45170G>A p.W15057* (on ENST00000591111; = p.W7633* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/154 reads (6%) | catalogued as COSV100626534; called by muse, mutect2
- ANO6 | c.1548C>T p.S516= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100263781; called by muse, mutect2
- EAF1 | c.69G>A p.E23= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV67541760; called by muse, mutect2, varscan2
- FBXW10 | c.756C>T p.Y252= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as rs765610933, COSV100111692; called by muse, mutect2
- HAVCR2 | c.240C>T p.S80= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100324948; called by muse, mutect2
- ICE1 | c.4308G>T p.V1436= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99665510; called by muse, mutect2
- OR6C76 | c.105G>C p.L35= | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as COSV100094273; called by muse, mutect2
- RNASEH2A | c.183G>A p.E61= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV55551128; called by muse, mutect2, varscan2
- SMCHD1 | c.3126C>T p.F1042= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV55269035, COSV99862387; called by muse, mutect2
- SORT1 | c.948T>C p.S316= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as COSV99861074; called by muse, mutect2
